Gene-level copy-number profile of tumor specimen ALCH-B1VW-TTP1-A from ALCHEMIST case ALCH-B1VW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,847 days).
Specimen ALCH-B1VW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8a0a6547-1e3a-474b-b6fe-1497d10b9768.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/621d3554-c258-430c-ac9b-fe45dad0b2f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 10,326; copy number 2: 46,163; copy number 3: 1,751; copy number 4: 57; copy number 5: 3; copy number 6: 1; copy number 11: 1; copy number 18: 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:44,934,055–44,946,071, 8 genes (within-gene range 0–2): AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3.
- chr2:96,112,876–96,147,012, 4 genes: ADRA2B, ASTL, DUSP2, AC012307.1.
- chr3:46,668,995–46,693,704, 1 gene: ALS2CL.
- chr3:125,916,620–125,930,024, 1 gene (within-gene range 0–2): FAM86JP.
- chr8:12,684,154–12,685,153, 1 gene: OR7E8P.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr12:131,828,393–131,851,783, 1 gene: MMP17.
- chr15:25,169,337–25,182,466, 8 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7.
- chr15:25,189,414–25,225,284, 20 genes (within-gene range 0–1): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:52,800,168–52,805,972, 1 gene: AC016044.1.
- chr16:70,661,204–70,801,160, 5 genes (within-gene range 0–2): MTSS2, AC020763.4, VAC14, AC020763.3, AC020763.1.
- chr16:70,778,433–70,779,145, 1 gene (within-gene range 0–1): AC027281.1.
- chr16:84,828,263–84,829,242, 1 gene (within-gene range 0–1): AC025280.1.
- chr17:39,603,536–39,696,797, 7 genes (within-gene range 0–2): NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3.
- chr18:79,420,836–79,422,780, 1 gene (within-gene range 0–1): AC018445.3.
- chr19:11,466,240–11,619,161, 12 genes (within-gene range 0–1): AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1, ZNF627, ACP5, GAPDHP76.
- chr19:34,481,758–34,512,304, 1 gene: WTIP.
- chr20:43,667,019–43,716,495, 1 gene: MYBL2.
- chr22:19,031,564–19,034,564, 1 gene: CA15P1.
- chr22:20,198,729–20,208,524, 2 genes: AC007663.2, LINC00896.
- chr22:23,059,415–23,145,021, 4 genes (within-gene range 0–1): RSPH14, GNAZ, Metazoa_SRP, U7.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–1): AC004882.1, AC004882.2, CABP7.
- chr22:41,922,032–41,958,933, 4 genes: TNFRSF13C, MIR378I, CENPM, LINC00634.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:44,107,373–44,210,114, 6 genes, copy number 5–18: PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 9,453. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
